Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AEND, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AEND-TTP1-A (Primary Tumor).

[page 1 of 15]
RUN DATE: [REDACTED] +2794
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

Specimen Inquiry

PAGE 1

PATIENT: [REDACTED]	ACCT #: [REDACTED]	LOC: [REDACTED]	U #: [REDACTED]
REG DR: [REDACTED]	AGE/SX: [REDACTED]	ROOM: [REDACTED]	REG: [REDACTED]
	DOB: [REDACTED]	BED: [REDACTED]	DIS: [REDACTED]
	STATUS: [REDACTED]	TLOC: [REDACTED]	

Spec #: [REDACTED] Received: [REDACTED] Status: SOUT Reg#: [REDACTED]
Spec Type: SURGICAL +2 Subm Dr: [REDACTED]

SPECIMEN SOURCE

Tissues: SIGMOID COLON - Sigmoid colon

CLINICAL HISTORY

Colon cancer

GROSS DESCRIPTION

The specimen submitted is labeled "Sigmoid colon". The specimen consists of a 15.5 cm in length x up to 5.5 cm in diameter portion of colon. A central ulcerated circumferential mass measuring 5.5 cm in length is noted. The tumor appears to extend into the superficial mesenteric adipose tissue. Tumor also shows direct extension to adhered omental adipose. An area of necrosis in the underlying mesenteric adipose tissue measuring 1.5 x 1.5 x 1.5 cm is noted. Blocks submitted: Blocks 1-2-3 - complete cross sections through tumor showing an area of omental involvement and abscessed area, block 4 - tumor showing extension into the mesentery, 5 - tissue from anastomotic rings, 6-9 - lymph nodes.

Dictated by: [REDACTED]

MICROSCOPIC DESCRIPTION

Sections of the colonic mucosa show moderately differentiated adenocarcinoma invading through the muscularis propria into the underlying mesentery. Capillary and lymphatic space invasion is identified. Perineural invasion is identified. Ten of twenty lymph nodes are positive for metastatic carcinoma.

FINAL PATH DIAGNOSIS

COLON, SIGMOID, SEGMENTAL RESECTION:

1. MODERATELY DIFFERENTIATED ADENOCARCINOMA.
2. PERINEURAL INVASION IDENTIFIED.
3. CAPILLARY AND LYMPHATIC SPACE INVASION IDENTIFIED.
4. MARGINS OF RESECTION ARE NEGATIVE FOR INVOLVEMENT WITH TUMOR.
5. TUMOR EXTENDS THROUGH MUSCULARIS PROPRIA.
6. TEN OF TWENTY LYMPH NODES ARE POSITIVE FOR METASTATIC CARCINOMA.

** CONTINUED ON NEXT PAGE **

[page 2 of 15]
SPEC #: [REDACTED]

PATIENT: [REDACTED]

(Continued)

Specimen: [REDACTED]

Received: [REDACTED] +2

(Continued)

ADDENDUM REPORT

Addendum #1

Entered: [REDACTED] +593

Evaluation of the paraffin embedded colon tumor shows KRAS gene mutation. The testing was performed at [REDACTED]

+593

Addendum Signed _____ (Electronic Signature) _____

STAGING CHECKLIST

STAGING CHECKLIST: COLON AND RECTUM, Resection

MACROSCOPIC

Specimen Type

☒ X Sigmoidectomy

Specimen Length

Specify: 15.5 cm

Tumor Site

☒ X Sigmoid colon

*Tumor Configuration

☒ X Exophytic (polypoid)☒ X Infiltrative☒ X Ulcerating

Tumor Size

Greatest dimension: 5.5 x 5.5 x 0.6 cm

*Intactness of Mesorectum

☒ X Not applicable

MICROSCOPIC

Histologic Type

☒ X Adenocarcinoma

Histologic Grade

☒ X Low-grade (well to moderately differentiated)

Pathologic Staging (pTNM)

Primary Tumor (pT)

☒ X pT3a/b: Tumor invades through the muscularis propria into the subserosa or the nonperitonealized pericolic or perirectal soft tissues, invades 5 mm or less beyond the border of the muscularis propria

** CONTINUED ON NEXT PAGE **

[page 3 of 15]
SPEC #: [REDACTED]

PATIENT: [REDACTED]

(Continued)

Specimen: [REDACTED]

Received: [REDACTED] +2

(Continued)

STAGING CHECKLIST

Regional Lymph Nodes (pN)X pN2: Metastasis in 4 or more regional lymph nodes

Specify: Number examined: 20

Number involved: 10

Distant Metastasis (pM)X pMX: Cannot be assessedMargins (check all that apply)Proximal MarginX Uninvolved by invasive carcinomaDistal MarginX Uninvolved by invasive carcinomaCircumferential (Radial) MarginX Not applicable

If all margins uninvolved by invasive carcinoma:

Distance of invasive carcinoma from closest margin: 1 mm

Specify margin: serosal

Lymphatic (Small Vessel) Invasion (L) (check all that apply)X PresentVenous (Large Vessel) Invasion (V) (check all that apply)X Absent*Perineural InvasionX Present*Tumor Border ConfigurationX Infiltrating*Intratumoral/Peritumoral Lymphocytic ResponseX Mild to moderate

+4

Signed _____ (signature on file) [REDACTED]

** END OF REPORT **

[page 4 of 15]
Initial Scan

+ Prior to +36 to +188

treatment

Name: [REDACTED]

DOB: [REDACTED]

Exam Date: [REDACTED]

+20

Room: [REDACTED]

Ord: [REDACTED]

Fam: [REDACTED]

MRN: [REDACTED]

Status: [REDACTED]

Pregnant: [REDACTED]

Accession: [REDACTED]

Radiologist: [REDACTED]

CPT: [REDACTED]

Exam: NM TUMOR IMAGE PET CT SKULL THIGH

R.T.: [REDACTED]

Ref#: [REDACTED]

EXAMDX: Colon Staging

History: The patient is a [REDACTED] female with a history of Stage 3C colon carcinoma of the sigmoid colon. No previous CT exams are available for review.

Procedure: Exam was performed following 14 mCi of Fluorine 18 FDG injected intravenously. CT was performed from the skull base to the mid thigh level for attenuation correction and localization purposes.

Findings: There is a 10 cm x 11 cm bulky nodal mass present in the porta hepatis which extends around the duodenum and involves the root of the mesentery. This has an SUV value measuring between 8 and 12. Additionally in the right axillary region there are three 8 mm to 10 mm lymph nodes present with increased metabolic activity with SUV values measuring in the 3.5-4 range. Remainder of activity in the chest and supraclavicular region and left axillary area is normal. The remainder of activity in the abdomen and pelvis is physiologic.

Impression:

1. Extensive adenopathy involving the region of the porta hepatis and root of the mesentery measuring 10 cm x 11 cm in size. Given the patient's history of colon carcinoma this would be suspicious for metastatic disease.
2. Right axillary increased metabolic activity in normal size lymph nodes. This may be inflammatory or metastatic in origin.

[page 5 of 15]
Scen Shaving CR

to [REDACTED] treatment

+36 to 188

Name: [REDACTED]
DOB: [REDACTED]

Exam Date: [REDACTED] +219
Room: [REDACTED]

Ord: [REDACTED]
Fam: [REDACTED]

MRN: [REDACTED]
Status: [REDACTED]
Pregnant: [REDACTED]
Accession: [REDACTED]
Radiologist: [REDACTED]
CPT: [REDACTED]

Exam: NM TUMOR IMAGE PET CT SKULL THIGH

R.T.: [REDACTED]

Ref#: [REDACTED]

EXAMDX: Colon Restaging

INDICATION: Colon cancer; restaging

COMPARISON: [REDACTED] and [REDACTED]
+125 +20

CORRELATIVE EXAMS:]

PROCEDURE: Flourine-18, 17.82mCi was administered intravenously as flourodeoxyglucose (FDG). Positron emission tomography was carried out from the skull base to the knees. Simultaneous CT imaging was carried out for attenuation correction and anatomic correlation.

FINDINGS:

CT Findings -

An effusion catheters present. The patient has undergone a cholecystectomy.

PET Findings -

There is physiologic tracer uptake in the liver, urinary system, and portions of the gut. There is a physiologically, mildly increased tracer uptake the gastroesophageal junction.

There is no abnormal tracer uptake about the body to suggest recurrent or metastatic colon cancer.

IMPRESSION:

1. Negative study, with no evidence of active metastatic colon cancer at this time.

2. The celiac and right axillary abnormalities seen last [REDACTED] have completely resolved.

[page 6 of 15]
Progression

Name: [REDACTED] Exam Date: [REDACTED] +566
DOB: [REDACTED] Home: [REDACTED] Room: [REDACTED]

Ord: [REDACTED] MRN: [REDACTED]
Fam: [REDACTED] Status: [REDACTED]

Exam: NM TUMOR IMAGE PET CT SKULL THIGH

R.T.: [REDACTED] Accession: [REDACTED]

Ref#: [REDACTED] Radiologist: [REDACTED]

EXAMDX: Colon Restaging CPT: [REDACTED]

CLINICAL HISTORY: This is a [REDACTED] female patient with a history of colon cancer who presents for restaging.

TECHNIQUE: PET images from the skull base to the distal thighs were obtained following the injection of 19.8 mCi of 18-FDG. Noncontrast CT images were acquired and fused to the PET study.

CORRELATIVE IMAGING: None
+219 +125

PREVIOUS STUDIES: [REDACTED] and [REDACTED]

FINDINGS:

CT images of the neck now reveal pathologically enlarged lymph nodes deep and posterior to the sternocleidomastoid muscle below the level of the hyoid bone (levels IIB and IV) bilaterally, extending inferiorly in a contiguous fashion to both supraclavicular nodal stations. Adenopathy is confirmed at the level of the thoracic inlet posterior to the sternum in the midline, and bulky adenopathy near the origin of the great vessels off the aortic arch on the left is noted. Representative standard uptake value measurements range up to 19 - 22.

Hypermetabolism is confirmed in pathologically enlarged lymph nodes in multiple nodal stations in the chest. These include posterior tracheal, aortopulmonic window, and subcarinal stations, and enlarged lymph nodes bordering the aortic arch on the left.

Images of the upper abdomen confirm borderline and pathologically enlarged lymph nodes near the celiac axis and origin of the SMA. Adenopathy is also confirmed in the paracaval, inter-aortocaval, and para-aortic retroperitoneal nodal stations.

The distribution of 18-FDG activity pelvis is normal. I do not see any evidence of pathologic adenopathy on the CT.

IMPRESSION: Abnormal study - significant interval change

1. Today's study confirms new pathologic adenopathy above and below the diaphragm (see above) suspicious for progressive metastatic disease.

[page 7 of 15]
Name: [REDACTED]
DOB: [REDACTED]

Exam Date: [REDACTED]
Room: [REDACTED]

+566

Ord: [REDACTED]
Fam: [REDACTED]

MRN: [REDACTED]
Status: [REDACTED]
Pregnant: [REDACTED]
Accession: [REDACTED]
Radiologist: [REDACTED]
CPT: [REDACTED]

Exam: NM TUMOR IMAGE PET CT SKULL THIGH
R.T.: [REDACTED]
Ref#: [REDACTED]

[REDACTED]

[page 8 of 15]
PR after

treatment

+581 - +734

Name:
DOB:
Home:

Exam Date: +765
Room:

Ord:
Fam:

MRN:

Status:

Pregnant:

Exam: NM TUMOR IMAGE PET CT
SKULL THIGH

Accession:

R.T.:
Ref#:

Radiologist:

CPT:

EXAMDX: Colon restaging

INDICATION: Colon cancer, restaging

COMPARISON: +646

PROCEDURE: Flourine-18, 16.2mCi was administered intravenously as flourodeoxyglucose (FDG). Positron emission tomography was carried out from the skull base to the mid thigh level. Simultaneous CT imaging was carried out for attenuation correction and anatomic correlation.

FINDINGS:

CT Findings - there is a 7 mm diameter lymph node in the right side of the neck (axial image 27) it appears slightly larger than on the prior exam. The previously noted sub centimeter diameter lymph nodes on both sides of the neck are no longer evident. Sub centimeter preaortic lymph nodes are stable to slightly smaller than previously. One of the two right periaortic lymph nodes at the level of the right renal pelvis has resolved. The other is smaller and now measures 1.0 x 0.5 cm compared with 1.3 x 8 1.2 cm, previously. A central venous catheter is in stable position. Changes of a cholecystectomy are again present. Surgical changes are again noted in the region of the sigmoid colon. Both lungs are clear. I see no nodules, lobar consolidation, pleural fluid or pneumothorax..

PET Findings - the aforementioned 7 mm diameter lymph node in the right side of the neck, that appeared slightly larger than previously, now has a maximum S U V of 6.2 compared with 4.2, previously. The previously noted areas of glucose accumulation elsewhere in the neck have resolved. Additionally, previously noted small areas of glucose accumulation in the mediastinum have resolved. The one right para-aortic lymph node that it is still present now has a maximum S U V of 1.8 compared with 4.2, previously.

IMPRESSION:

1. There is a 7 mm diameter lymph node in the right side the neck incision axial image 27) which is slightly larger than on the prior exam and has more glucose accumulation than previously. By itself, it would be worrisome for

[page 9 of 15]
Name: [REDACTED] Exam Date: [REDACTED] +765
DOB: [REDACTED] Room:
Hone: [REDACTED]

Ord: [REDACTED] MRN: [REDACTED]
Fam: [REDACTED] Status: [REDACTED]
Pregnant: [REDACTED]
Exam: NM TUMOR IMAGE PET CT Accession: [REDACTED]
SKULL THIGH
R.T.: [REDACTED] Radiologist: [REDACTED]
Ref#: [REDACTED] CPT: [REDACTED]

worsening metastatic disease. However, the previously noted multiple other sites of abnormal adenopathy in the neck, mediastinum and retroperitoneum have either resolved or decreased in size and glucose avidity. As such, this enlarging more glucose avid lymph node on the right side of the neck is of indeterminate nature. 2. Changes of a cholecystectomy and surgery in the distal colon again present...

[REDACTED]

[page 10 of 15]
after

treatment

+744 - +1021

Name:

DOB:

Home:

Exam Date: +1020

Room:

Ord:

Fam:

MRN:

Status:

Pregnant:

Exam: NM TUMOR IMAGE PET CT
SKULL THIGH

Accession:

R.T.:

Radiologist:

Ref#:

CPT:

EXAMDX: Colon Restaging

INDICATION: Colon cancer, restaging

COMPARISON: +880

PROCEDURE: Flourine-18, 16.9mCi was administered intravenously as flourodeoxyglucose (FDG). Positron emission tomography was carried out from the skull base to the lower thigh level. Simultaneous CT imaging was carried out for attenuation correction and anatomic correlation.

FINDINGS:

CT Findings - There is a new 1.5 cm diameter retrocaval lymph node at the level of the kidneys (axial image 99). The 1 cm diameter lymph node on the right side of the neck is stable size (image 25). Changes of a cholecystectomy are again noted. I see no pulmonary nodules, pleural fluid or lung consolidation

PET Findings - The new 1.5 cm diameter retrocaval lymph node has abnormal glucose accumulation with a maximum SUV of 14.6. Glucose uptake in the lymph node on the right side of the neck has increased slightly and now has a maximum SUV of 3.8 compared with 2.7, previously

IMPRESSION:

1. Presumed new 1.5 cm diameter metastatic lymph node in the retroperitoneum on the right.
2. Mildly abnormal glucose accumulation associated with the previously noted 1 cm diameter lymph node on the right side of the neck has increased mildly.

[page 11 of 15]
CR
after Irinotecan

Name:
DOB:
Home:

Exam Date: +1160
Room:

Ord:
Fam:

MRN:

Status:

Pregnant:

Exam: NM TUMOR IMAGE PET CT
SKULL THIGH

Accession:

R.T.:

Radiologist:

Ref#:

CPT:

EXAMDX: Colon Restaging

CLINICAL HISTORY: This is a female patient with a history of colon cancer who presents for restaging.

TECHNIQUE: PET images from the skull base to the distal thighs were obtained following the injection of 16.1 mCi of 18-FDG. Noncontrast CT images were acquired and fused to the PET study. The patient's blood glucose was 84 at the time of imaging.

CORRELATIVE IMAGING: None

PREVIOUS STUDIES: +1020

FINDINGS:

The distribution of 18-FDG activity in the head/neck region today is normal. The previously reported uptake in the lower cervical region on the right, presumably nodal activity, is not evident on the current exam.

The distribution of 18-FDG activity in the chest is within normal limits. CT images reveal no suspicious pulmonary nodules or pathologically enlarged lymph nodes.

The prior study disclosed two foci of hypermetabolism in the midabdomen correlating with pathologically enlarged retrocaval and anterior para-aortic lymph nodes. These foci of uptake are not present on the current exam, and no pathologically enlarged lymph nodes are evident on CT. There is persistent mild uptake noted near the anterior margin of the left iliac crest, presumably related to inflammatory changes (probable muscle strain).

IMPRESSION: Negative study

[page 12 of 15]
Name:

DOB:

Home:

Exam Date: +1160

Room:

Ord:

Fam:

MRN:

Status:

Pregnant:

Exam: NM TUMOR IMAGE PET CT
SKULL THIGH

Accession:

R.T.:

Ref#:

Radiologist:

CPT:

metastatic disease.

[page 13 of 15]
Patient Information

Latest Scan

Name: [REDACTED]
Medical Record Number: [REDACTED]
Sex Code: [REDACTED]
Birth Date: [REDACTED]
SSN: [REDACTED]

Exam Information

Accession Number: [REDACTED]
Modality: CT
Body Part: CAP
Description: CT CHEST-ABDOMEN-PELVIS W CONT
Performed Date: [REDACTED] +2584
Patient History: Malignant neoplasm of sigmoid colon; Secondary and unsp malignant neoplasm of lymph node, unsp
Comments: [REDACTED]

Final Report

EXAM: CT CHEST-ABDOMEN-PELVIS W CONT

CLINICIAN'S HISTORY: Malignant neoplasm of sigmoid colon; Secondary and unsp malignant neoplasm of lymph node, unsp

ADDITIONAL CLINICAL INDICATIONS: ---

COMPARISON STUDIES: Previous chest abdomen and pelvis CT studies dated [REDACTED] +2382 and [REDACTED] +1455

TECHNIQUE: Helical CT images of the chest abdomen and pelvis are performed with the intravenous administration of 96 mL Isovue-300 contrast material. Enteric contrast was given.

+1455 CHEST FINDINGS: Pleural-based nodularity with calcification is again seen in the medial right lower lobe unchanged from [REDACTED] +1455. There is also some linear scarring in the right middle lobe similar to the [REDACTED] study. An acute airspace consolidation or new parenchymal lung mass is not identified. No enlarged mediastinal, hilar, or axillary lymph nodes are identified. The thyroid gland is unremarkable. An Infuse-a-Port catheter is present which enters the left subclavian approach. The tip is in the mid SVC. No destructive bony lesions appreciated. Degenerative changes are present in the lower thoracic spine with some prominent anterior lateral bony spurs.

CHEST IMPRESSIONS:

1. Unchanged CT examination of the chest no evidence of metastatic disease identified.

+2382 ABDOMEN FINDINGS: A focal area of low density is present anteriorly in the medial segment left lobe of the liver adjacent to the falciform ligament [REDACTED] on the portal venous phase images measuring 10 mm in diameter. That area becomes isodense on delayed phase imaging. There is a very similar appearing lesion in this area on the [REDACTED] study. The area is virtually imperceptible on the [REDACTED] examination. While that is a frequent location for focal fatty infiltration of the liver, focal fat should not become isodense on delayed phase imaging. I cannot exclude a more significant hepatic lesion, including primary and secondary neoplasms. No other hepatic lesions are seen. The gallbladder is surgically absent. The extrahepatic bile ducts are dilated with the common bile duct today measuring 10 mm in diameter. The common duct measured 6 mm in diameter on the [REDACTED] study. No intrahepatic ductal +1455

+2382

[page 14 of 15]
dilatation is seen. The spleen, pancreas, adrenal glands, and kidneys are normal. No enlarged retroperitoneal adenopathy is seen. The enteric contrast in the stomach and proximal small bowel does not appear to be uniformly mixed with some areas of clumping and high density contrast. No definite bowel lesions identified..

ABDOMEN IMPRESSIONS:

1. Small lesion anteriorly in the liver. Again this is nonspecific. While it is in a site frequently involved with focal fatty infiltration, it does appear to show enhancement on the delayed phase when it becomes isodense with the remainder of the liver. MRI of the liver with in and out of phase imaging may be helpful to further characterize. Alternatively dedicated ultrasound could be performed to see if there is a discernible lesion.
2. Status post cholecystectomy with dilated extrahepatic bile ducts today increased compared to the study in [REDACTED]. Clinical correlation with liver function tests to see if there is an obstructive pattern would be recommended.

PELVIS FINDINGS: Postoperative changes are present consistent with the provided history of sigmoid colectomy. The orally administered contrast has passed through all of the small bowel and colon. The bowel loops appear unremarkable. No enlarged pelvic lymph nodes identified. No ascites is present in the pelvis. The uterus is anteverted. It is normal in size. No adnexal masses detected. Atherosclerotic calcifications are present in the abdominal aorta and iliac arteries without aneurysm. Bony structures show degenerative change in the lumbar spine. No destructive lesions detected.

PELVIS IMPRESSIONS:

1. Postoperative change consistent with patient's history. No acute pelvic pathology identified. No evidence of metastatic disease detected.

Electronically signed by: [REDACTED]
Dictated: [REDACTED] +2584
Signed: [REDACTED] +2584

Principal Interpreter

Name: [REDACTED]
Provided: [REDACTED]

[page 15 of 15]
SPECIMEN SOURCE

Tissues: SIGMOID COLON - Sigmoid colon

ICD-0-3

adenocarcinoma, NOS 8140/3
Site: Sigmoid colon C18.7

CLINICAL HISTORY

Colon cancer

ICD-10

C18.7

fw 4/24/14

GROSS DESCRIPTION

The specimen submitted is labeled "Sigmoid colon". The specimen consists of a 15.5 cm in length x up to 5.5 cm in diameter portion of colon. A central ulcerated circumferential mass measuring 5.5 cm in length is noted. The tumor appears to extend into the superficial mesenteric adipose tissue. Tumor also shows direct extension to adhered omental adipose. An area of necrosis in the underlying mesenteric adipose tissue measuring 1.5 x 1.5 x 1.5 cm is noted. Blocks submitted: Blocks 1-2-3 - complete cross sections through tumor showing an area of omental involvement and abscessed area, block 4 - tumor showing extension into the mesentery, 5 - tissue from anastomotic rings, 6-9 - lymph nodes.

MICROSCOPIC DESCRIPTION

Sections of the colonic mucosa show moderately differentiated adenocarcinoma invading through the muscularis propria into the underlying mesentery. Capillary and lymphatic space invasion is identified. Perineural invasion is identified. Ten of twenty lymph nodes are positive for metastatic carcinoma.

FINAL PATH DIAGNOSIS

COLON, SIGMOID, SEGMENTAL RESECTION:

1. MODERATELY DIFFERENTIATED ADENOCARCINOMA.
2. PERINEURAL INVASION IDENTIFIED.
3. CAPILLARY AND LYMPHATIC SPACE INVASION IDENTIFIED.
4. MARGINS OF RESECTION ARE NEGATIVE FOR INVOLVEMENT WITH TUMOR.
5. TUMOR EXTENDS THROUGH MUSCULARIS PROPRIA.
6. TEN OF TWENTY LYMPH NODES ARE POSITIVE FOR METASTATIC CARCINOMA.

Source: NCI Genomic Data Commons file 3f3659a9-8bde-4e02-a951-92afae78f914 (ER0349 ER-AEND Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).